Somatic mutation profile of tumor specimen MMRF_2284_1_BM_CD138pos (aliquot MMRF_2284_1_BM_CD138pos_T1_KHS5U_L09539) from MMRF case MMRF_2284, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.9 years (24,818 days).
Specimen MMRF_2284_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5bfa444-edb0-47dc-9ffd-14b91a9cf8b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2284_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2284_1_PB_Whole_C2_KHS5U_L09540; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a9256e6-4f34-40de-a336-03b28cb8dae5

The open-access MAF lists 128 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 27, Intron 13, Silent 11, 5'UTR 6, Nonsense Mutation 5, RNA 5, 3'Flank 5, 5'Flank 5, Splice Site 2, Splice Region 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.10154T>A p.L3385* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV67995701; called by muse, mutect2, varscan2
- ATP4A | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs780650317; called by muse, mutect2
- ATP7B | c.3797G>T p.G1266V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM131494, CM970148, COSV54440724; called by muse, mutect2, varscan2
- CSMD1 | c.8875C>T p.R2959C (on ENST00000520002; = p.R2958C on NM_033225.6) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773539685, COSV59306417; called by muse, mutect2, varscan2
- ERBB4 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53512410; called by muse, mutect2
- ETV4 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1304464107; called by muse, mutect2, varscan2
- GET1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs745364854, COSV100414408; called by muse, mutect2
- HMCN2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs782130658; called by muse, mutect2, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 43/82 reads (52%) | catalogued as rs181922188; called by muse, mutect2
- IGLV3-1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs574479963; called by muse, mutect2, varscan2
- IRX1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116798; called by muse, mutect2, varscan2
- KMT2C | c.11842C>G p.Q3948E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1055248357, COSV51460874; called by muse, mutect2
- LACTBL1 | c.88C>A p.R30S (on ENST00000618559; = p.R59S on NM_001289974.2) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as rs762072024; called by muse, mutect2, varscan2
- MAP7D1 | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746024263; called by muse, mutect2, varscan2
- MAPK8 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs752334346; called by mutect2, varscan2
- OLFM1 | c.878G>A p.R293H (on ENST00000371793 / NM_001282611.2; = p.R275H on NM_014279.5) | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); catalogued as rs1259537651, COSV53279856; called by muse, varscan2
- OR5L1 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs778351093, COSV100449964; called by muse, mutect2, varscan2
- PKHD1 | c.6901G>A p.V2301M | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs376179014; called by muse, mutect2, varscan2
- SLC22A16 | c.533+8C>A | Splice Region (SNP) | VAF 26/48 reads (54%) | catalogued as rs758081810; called by muse, mutect2, varscan2
- SYNE2 | c.17853G>T p.M5951I | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs927893165; called by muse, mutect2, varscan2
- TGFBR2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV55460151; called by muse, mutect2
- ADCY7 | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALS2CL | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ASXL3 | c.3000A>T p.E1000D | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAPN6 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2
- CCNT1 | c.1008del p.S337Pfs*7 | Frame Shift Del (DEL) | VAF 43/125 reads (34%) | called by mutect2, pindel, varscan2
- COBLL1 | c.1630A>C p.S544R (on ENST00000392717; = p.S506R on NM_014900.5) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOP1B | c.2622+1G>C p.X874_splice | Splice Site (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- DPYSL3 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- FAM237A | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.299); called by muse, mutect2
- H3C7 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HECW2 | c.4156C>T p.R1386* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- IGHV2-70 | c.146_147insTATTAGTGCAG p.T50Ifs*10 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | called by pindel, varscan2
- IGKV1D-13 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- IL1A | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2
- IRF1 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRP12 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | called by muse, mutect2, varscan2
- NPTXR | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- OR14A16 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- P2RY10 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDHA9 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- POLA1 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PRKD1 | c.2327G>T p.S776I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- QRFPR | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RBMS3 | c.905G>A p.W302* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- SEMA3A | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SMARCC2 | c.1390_1392del p.A464del | In Frame Del (DEL) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- SPATA12 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPATA31D1 | c.3541G>T p.E1181* | Nonsense Mutation (SNP) | VAF 59/92 reads (64%) | called by muse, mutect2, varscan2
- TMEM45B | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- URB1 | c.4241G>T p.R1414I | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF410 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZNF469 | c.6044G>T p.R2015M (on ENST00000437464; = p.R2043M on NM_001367624.2) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCC9 | c.3360C>T p.L1120= | Silent (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- ABI3 | c.1038C>T p.C346= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs760609644; called by muse, varscan2
- CDH9 | c.795T>C p.P265= | Silent (SNP) | VAF 107/180 reads (59%) | catalogued as COSV50513421; called by muse, mutect2, varscan2
- CHRNA4 | c.1347C>T p.C449= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- EYA2 | c.723G>A p.P241= | Silent (SNP) | VAF 100/204 reads (49%) | catalogued as rs892426959; called by muse, mutect2, varscan2
- FASTKD5 | c.1239A>C p.A413= | Silent (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- NAF1 | c.1305C>A p.P435= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- PEG10 | c.912C>T p.Y304= (on ENST00000482108 / NM_001040152.2; = p.Y338= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV71788715; called by muse, mutect2
- PLXNA4 | c.561G>A p.T187= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs772947706, COSV58129918; called by muse, mutect2, varscan2
- TTYH3 | c.1395C>T p.T465= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs758485529; called by muse, mutect2, varscan2
- VSIG10L | c.1752G>A p.L584= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- AC118942.1 | n.796-1585T>C | Intron (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- AC142381.3 | n.383C>T | RNA (SNP) | VAF 12/18 reads (67%) | catalogued as rs539168544; called by muse, mutect2, varscan2
- ACP3 | c.*1345C>G | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- ADCY5 | c.2930+28G>A | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as rs1192578432; called by muse, mutect2, varscan2
- AHRR | c.*568C>T | 3'UTR (SNP) | VAF 9/116 reads (8%) | catalogued as rs73038991, COSV57093013; called by muse, mutect2
- ATXN10 | c.895-4319A>G | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs918052757; called by muse, mutect2, varscan2
- B4GALNT4 | c.985+9G>A | Intron (SNP) | VAF 35/126 reads (28%) | called by muse, mutect2, varscan2
- BCAT1 | c.*43G>T | 3'UTR (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- C1orf21 | c.*100T>A | 3'UTR (SNP) | VAF 119/239 reads (50%) | called by muse, mutect2, varscan2
- CCNC | c.*703C>T | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- CDC42SE2 | c.*2164T>G | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- CIAO1 | c.*129G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs969395250; called by muse, mutect2, varscan2
- COL9A1 | c.*718G>T | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- CSRNP3 | c.*2356G>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- EIF2S3B | chr12:10505835 G>A | 5'Flank (SNP) | VAF 22/62 reads (35%) | catalogued as rs891432585; called by muse, varscan2
- FAM189A1 | c.*1149A>T | 3'UTR (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- FBN1 | c.164+1194A>G | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- FGF23 | c.*2086A>C | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- FOXL1 | c.-89C>A | 5'UTR (SNP) | VAF 22/28 reads (79%) | called by muse, mutect2, varscan2
- FRYL | c.*143A>C | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- FUT7 | chr9:137036567 C>A | 5'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- GALNT11 | c.586+420G>T | Intron (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- IGLL5 | c.-96C>T | 5'UTR (SNP) | VAF 20/57 reads (35%) | catalogued as rs143799402, COSV73250060, COSV73250979; called by muse, mutect2, varscan2
- KIR3DL2 | c.-10C>T | 5'UTR (SNP) | VAF 14/188 reads (7%) | catalogued as rs1445301494; called by muse, mutect2
- KLF15 | c.-18C>T | 5'UTR (SNP) | VAF 35/70 reads (50%) | catalogued as rs751346481; called by muse, mutect2, varscan2
- LIMCH1 | c.936-7706T>C | Intron (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- LINC00692 | n.633T>A | RNA (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- LRAT | c.*1771C>A | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4562T>C | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by mutect2, varscan2
- LRFN4 | c.*151C>T | 3'UTR (SNP) | VAF 6/65 reads (9%) | catalogued as rs760052838; called by muse, mutect2, varscan2
- LRRC2 | chr3:46515527 G>C | 3'Flank (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- LRRC2 | chr3:46517210 G>A | 3'Flank (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- MAEA | c.69+8074C>T | Intron (SNP) | VAF 30/56 reads (54%) | catalogued as rs1560327952; called by muse, mutect2, varscan2
- MDGA1 | c.-949G>A | 5'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- MIR2054 | n.6A>G | RNA (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- MIR5195 | chr14:106851126 T>A | 5'Flank (SNP) | VAF 64/149 reads (43%) | catalogued as rs569234583; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851258 C>T | 5'Flank (SNP) | VAF 49/100 reads (49%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- MPEG1 | c.*5C>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs561084360, COSV99915407; called by muse, mutect2, varscan2
- MUC6 | c.3808+71C>A | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- NECTIN1 | c.-86G>A | 5'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- PARD3 | c.2227+1538A>G | Intron (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- PPP1R12B | c.*6413G>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | catalogued as rs1399187088; called by muse, mutect2, varscan2
- RRM2B | c.*2998C>G | 3'UTR (SNP) | VAF 8/203 reads (4%) | called by muse, mutect2
- SEMA4A | c.-29-163G>C | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- SLC18A1 | c.*76G>T | 3'UTR (SNP) | VAF 68/151 reads (45%) | catalogued as COSV99368708; called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624793 A>C | 3'Flank (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- SORCS3 | c.*577T>G | 3'UTR (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133554305 C>T | 3'Flank (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- TBC1D4 | c.*828G>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- THADA | c.4343+166A>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- TPCN2 | c.1539+316C>T | Intron (SNP) | VAF 16/167 reads (10%) | catalogued as rs1199794831; called by muse, mutect2
- UBE2DNL | n.401G>T | RNA (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- UBE2DNL | n.507C>A | RNA (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- UQCC1 | c.*303G>A | 3'UTR (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- Unknown | chr11:119500440 del ATG | IGR (DEL) | VAF 31/58 reads (53%) | called by mutect2, pindel, varscan2
- WDR77 | c.*1007C>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | catalogued as rs1293587955; called by muse, mutect2, varscan2
- WHAMMP2 | chr15:28763644 C>T | 3'Flank (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- WNT7A | c.*2466A>G | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- WWC2 | c.*1171dup | 3'UTR (INS) | VAF 45/99 reads (45%) | called by mutect2, pindel, varscan2
- WWOX | c.*279C>T | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs140398425; called by muse, mutect2, varscan2
- ZHX3 | c.*2210_*2231del | 3'UTR (DEL) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- ZNF606 | chr19:58006836 C>T | 5'Flank (SNP) | VAF 9/63 reads (14%) | catalogued as rs956842419; called by muse, mutect2, varscan2
